Somatic mutation profile of tumor specimen TCGA-D5-6531-01A (aliquot TCGA-D5-6531-01A-11D-1719-10) from TCGA case TCGA-D5-6531, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.7 years (27,633 days).
Specimen TCGA-D5-6531-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9748f7eb-40c7-467f-8403-80930c09497d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6531-10A (Blood Derived Normal), aliquot TCGA-D5-6531-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb927e9d-0ad6-4a9a-9fcc-65e8f5e58f4e

The open-access MAF lists 199 somatic variants for this specimen: 156 protein-altering or splice-affecting, 43 silent.
By variant classification: Missense Mutation 135, Silent 43, Nonsense Mutation 7, Frame Shift Del 5, Splice Site 4, In Frame Del 3, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1778C>T p.T593M | Missense Mutation (SNP) | VAF 108/222 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571555115, CM1313638, COSV55932538; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 63/154 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 70/116 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1196_1213del p.S399_L404del (on ENST00000521381 / NM_181523.3; = p.S129_L134del on NM_181504.4) | In Frame Del (DEL) | VAF 66/92 reads (72%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 58/85 reads (68%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as rs540868706, COSV54049978; called by muse, mutect2, varscan2
- A2ML1 | c.729-1G>C p.X243_splice | Splice Site (SNP) | VAF 13/78 reads (17%) | catalogued as COSV55286570; called by muse, mutect2, varscan2
- ABCA9 | c.2192A>G p.K731R | Missense Mutation (SNP) | VAF 282/528 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV60621248; called by muse, mutect2, varscan2
- ACIN1 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 173/511 reads (34%) | catalogued as COSV52973718; called by muse, mutect2, varscan2
- ACSL6 | c.58C>A p.Q20K (on ENST00000379240; = p.Q45K on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV57294996; called by muse, mutect2, varscan2
- ADAM12 | c.2462C>T p.P821L | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV64124887, COSV64130633; called by muse, mutect2
- ADAM32 | c.2237G>T p.S746I | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as rs200400990, COSV101165358; called by muse, mutect2, varscan2
- ADAMTS16 | c.2084C>A p.S695* | Nonsense Mutation (SNP) | VAF 79/235 reads (34%) | catalogued as COSV56980147; called by muse, mutect2, varscan2
- ADAMTS16 | c.2855T>A p.V952E | Missense Mutation (SNP) | VAF 49/260 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV56980164; called by muse, mutect2, varscan2
- AFAP1L2 | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs760017215, COSV58412622; called by muse, mutect2, varscan2
- AFF2 | c.2647T>C p.C883R | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53978690; called by muse, varscan2
- AGBL5 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV59935679; called by muse, mutect2, varscan2
- AKAP13 | c.6676G>T p.D2226Y (on ENST00000394518 / NM_007200.5; = p.D2230Y on NM_006738.6) | Missense Mutation (SNP) | VAF 42/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100773507; called by muse, mutect2, varscan2
- ANKRD52 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 100/170 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57282888; called by muse, mutect2, varscan2
- APC | c.4480del p.E1494Kfs*13 | Frame Shift Del (DEL) | VAF 80/100 reads (80%) | catalogued as CD108356, COSV57321403, COSV57381675; called by mutect2, pindel*, varscan2
- ARFGEF1 | c.980A>G p.D327G | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51603325; called by muse, mutect2, varscan2
- ARHGAP22 | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV50933586; called by muse, mutect2, varscan2
- ASTN1 | c.2494G>T p.A832S | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56062554; called by muse, mutect2, varscan2
- ATP10A | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 67/86 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV63514179; called by muse, mutect2, varscan2
- BEST1 | c.1097T>A p.I366N | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56444665; called by muse, mutect2, varscan2
- BMP8A | c.1097G>C p.C366S | Missense Mutation (SNP) | VAF 155/254 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV59032303; called by muse, mutect2, varscan2
- CAMTA1 | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.006); catalogued as rs772482641, COSV57884321; called by muse, mutect2, varscan2
- CARS1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1396843622, COSV53453537; called by muse, varscan2
- CCDC136 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV52796712; called by muse, mutect2, varscan2
- CD5L | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs202111822; called by muse, mutect2, varscan2
- CHDH | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1056830571, COSV100179649; called by muse, mutect2, varscan2
- COL22A1 | c.4855C>T p.R1619W | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs755307992, COSV57325647; called by muse, mutect2, varscan2
- CREBRF | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs1374899614, COSV99755663; called by muse, mutect2, varscan2
- CSH1 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 81/350 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs769023878, COSV100298304; called by muse, varscan2
- CSMD3 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV52113522; called by muse, mutect2, varscan2
- DBX1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV57053582; called by muse, mutect2
- DCLK1 | c.2093G>A p.R698Q (on ENST00000360631 / NM_001330072.2; = p.D723N on NM_004734.5) | Missense Mutation (SNP) | VAF 77/287 reads (27%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.341); catalogued as COSV55174349; called by muse, mutect2, varscan2
- DDR2 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371333028; called by muse, mutect2, varscan2
- DECR2 | c.149+1G>A p.X50_splice | Splice Site (SNP) | VAF 156/476 reads (33%) | catalogued as rs753013921, COSV54791007; called by muse, mutect2, varscan2
- DLGAP4 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as rs575670266, COSV59414947; called by muse, mutect2, varscan2
- DNAJC21 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100331339; called by muse, mutect2
- DOCK2 | c.4108C>T p.R1370* | Nonsense Mutation (SNP) | VAF 22/130 reads (17%) | catalogued as COSV56944597; called by muse, mutect2, varscan2
- DOCK5 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52396789; called by muse, mutect2, varscan2
- DPH2 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 103/383 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV52542660; called by muse, mutect2, varscan2
- DPP3 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV100855550; called by muse, mutect2, varscan2
- DSCAM | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1156542414, COSV101259763; called by muse, varscan2
- EMSY | c.2982G>A p.M994I | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.053); catalogued as COSV58257842; called by muse, mutect2, varscan2
- EPHA5 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765807043, COSV56630579, COSV56683300; called by muse, mutect2, varscan2
- EVC2 | c.1201C>A p.Q401K | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV60388501; called by muse, mutect2, varscan2
- FAM120C | c.3115G>A p.A1039T | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs782023167, COSV60260319, COSV60263078; called by muse, mutect2, varscan2
- FAM160B1 | c.124+1G>C p.X42_splice | Splice Site (SNP) | VAF 104/255 reads (41%) | catalogued as COSV65086281; called by muse, mutect2, varscan2
- FAM71A | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as rs200512242, COSV54234765; called by muse, mutect2, varscan2
- FAT3 | c.8269G>A p.V2757I | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs374977464; called by muse, mutect2, varscan2
- FBXL7 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61641895; called by muse, mutect2, varscan2
- FMO5 | c.1291del p.D431Tfs*3 | Frame Shift Del (DEL) | VAF 46/139 reads (33%) | catalogued as COSV54204771; called by mutect2, pindel, varscan2
- FNBP1 | c.1574A>G p.E525G | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV100852652; called by muse, mutect2, varscan2
- FRAS1 | c.7010C>T p.A2337V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs748365788, COSV53593223; called by muse, mutect2, varscan2
- GLI3 | c.3605A>C p.Q1202P | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV67885692; called by muse, mutect2, varscan2
- GLP1R | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs200849157; called by muse, mutect2, varscan2
- GLT6D1 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 103/140 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs768446480, COSV65627121; called by muse, mutect2, varscan2
- GRIN3A | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100701457; called by muse, mutect2, varscan2
- GRM3 | c.1033A>C p.N345H | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64467866; called by muse, mutect2, varscan2
- GRM3 | c.1034A>T p.N345I | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467879; called by muse, mutect2, varscan2
- GTF2F1 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 149/336 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV99831726; called by muse, varscan2
- HNRNPCL1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 143/200 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs4026148, COSV58610262; called by muse, mutect2, varscan2
- HS6ST3 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs775008092, COSV65003042; called by muse, mutect2, varscan2
- IKZF1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.427); catalogued as COSV58781791; called by muse, mutect2, varscan2
- IL22 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1457566187, COSV60159830, COSV60160466; called by muse, mutect2, varscan2
- IRX1 | c.244T>A p.Y82N | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57358246; called by muse, mutect2, varscan2
- JAG2 | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 168/350 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs368191747; called by muse, mutect2, varscan2
- KCNH8 | c.2618A>T p.E873V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV60457580; called by muse, mutect2, varscan2
- KCNQ3 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 92/324 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1158471159, COSV66464609; called by muse, mutect2, varscan2
- KCNT1 | c.2075C>T p.A692V (on ENST00000488444; = p.A711V on NM_020822.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs1312096992, COSV53696431; called by muse, mutect2, varscan2
- KCNV2 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773122223, COSV66055593; called by muse, mutect2, varscan2
- KRT6A | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 184/326 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as rs201376827; called by muse, mutect2, varscan2
- KRTAP20-1 | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 494/1146 reads (43%) | PolyPhen possibly damaging (0.642); catalogued as COSV100228758; called by muse, mutect2, varscan2
- L3MBTL4 | c.1423G>C p.D475H | Missense Mutation (SNP) | VAF 61/434 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV53114557; called by muse, mutect2, varscan2
- LPAR4 | c.883A>T p.I295F | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV70912268; called by muse, mutect2, varscan2
- MACF1 | c.19885G>C p.D6629H (on ENST00000372915; = p.D4674H on NM_012090.5) | Missense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as COSV57109016; called by muse, mutect2, varscan2
- MIER3 | c.1052+1G>A p.X351_splice (on ENST00000381199 / NM_001297599.2; = p.X350_splice on NM_152622.4) | Splice Site (SNP) | VAF 15/178 reads (8%) | catalogued as COSV67082982; called by muse, mutect2
- MMP24 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 216/341 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs759744987, COSV55769391, COSV55774057; called by muse, mutect2, varscan2
- MYC | c.1262G>A p.R421Q (on ENST00000377970; = p.R436Q on NM_002467.6) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs761932135, COSV99420051; called by muse, mutect2, varscan2
- MYH1 | c.893C>A p.P298Q | Missense Mutation (SNP) | VAF 133/194 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs1567722526, COSV56844331; called by muse, mutect2, varscan2
- NCOA5 | c.675G>A p.M225I | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.742); catalogued as COSV99275445; called by muse, mutect2, varscan2
- NDE1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as rs536800933, COSV100707346, COSV61270085; called by muse, mutect2, varscan2
- NFASC | c.2488C>T p.R830C (on ENST00000339876 / NM_001378329.1; = p.R933C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs775709334, COSV58360118; called by muse, mutect2, varscan2
- NPHP4 | c.181T>A p.S61T | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV65393397; called by muse, mutect2, varscan2
- OR1M1 | c.775T>A p.Y259N | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70036510; called by muse, mutect2, varscan2
- OR5AN1 | c.914T>C p.L305S | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as COSV58321664; called by muse, mutect2
- OR8B3 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs373419493, COSV63541260, COSV63541402; called by muse, mutect2, varscan2
- PAPOLA | c.1352A>C p.N451T | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV99354147; called by muse, mutect2, varscan2
- PAPSS1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99491964; called by muse, mutect2, varscan2
- PARD3B | c.2277G>T p.K759N (on ENST00000406610 / NM_001302769.2; = p.K697N on NM_152526.6) | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV62504111; called by muse, mutect2, varscan2
- PARD6G | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs748057470, COSV62060394; called by muse, mutect2, varscan2
- PBX1 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63341415; called by muse, mutect2, varscan2
- PCDHGB6 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV53906831; called by muse, mutect2, varscan2
- PEG3 | c.223T>G p.L75V | Missense Mutation (SNP) | VAF 110/232 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55626515; called by muse, mutect2, varscan2
- PHLDA1 | c.447A>C p.K149N | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56996812; called by muse, mutect2, varscan2
- PNLIP | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.144); catalogued as COSV65039801; called by muse, mutect2, varscan2
- PREX1 | c.3338G>A p.G1113D | Missense Mutation (SNP) | VAF 91/152 reads (60%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1368959457, COSV64248377, COSV64248801; called by muse, mutect2, varscan2
- PRRC2B | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375283040; called by muse, mutect2, varscan2
- PSAP | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs545627914, COSV56450422; called by muse, mutect2, varscan2
- PTPRA | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755190193, COSV53778809; called by muse, mutect2, varscan2
- SAFB2 | c.606G>A p.P202= | Splice Region (SNP) | VAF 63/163 reads (39%) | catalogued as rs775548479, COSV53041849; called by muse, mutect2, varscan2
- SDHA | c.1740C>G p.Y580* | Nonsense Mutation (SNP) | VAF 579/1180 reads (49%) | catalogued as COSV53765808; called by muse, mutect2, varscan2
- SEC14L3 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs760882036, COSV53178182; called by muse, mutect2, varscan2
- SFMBT2 | c.2351C>T p.A784V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1448090593, COSV62806085; called by muse, mutect2, varscan2
- SIGLEC8 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV58472117, COSV99068127; called by muse, mutect2, varscan2
- SIX2 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57390181; called by muse, mutect2, varscan2
- SLC23A2 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); catalogued as COSV57771689; called by muse, mutect2, varscan2
- SLC8A1 | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60472469, COSV60499841; called by muse, mutect2, varscan2
- SLIT1 | c.4442G>A p.R1481H | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs148906362; called by muse, mutect2, varscan2
- SLIT3 | c.4548G>C p.E1516D | Missense Mutation (SNP) | VAF 54/68 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV60594709; called by muse, mutect2, varscan2
- SMOC1 | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV62759693; called by muse, mutect2, varscan2
- SMOC2 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV100634956; called by muse, varscan2
- SORL1 | c.23G>T p.R8M | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.237); catalogued as COSV99493476; called by muse, mutect2, varscan2
- SYNE1 | c.25069C>T p.R8357C (on ENST00000367255 / NM_182961.4; = p.R8309C on NM_033071.3) | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs755199419, COSV54905054, COSV55072864; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.24805C>T p.R8269W (on ENST00000367255 / NM_182961.4; = p.R8198W on NM_033071.3) | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778418319, COSV54961258; called by muse, mutect2, varscan2
- SYNPO2 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs756133104, COSV61107334, COSV61112769; called by muse, mutect2, varscan2
- TAB2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs374508964; called by muse, mutect2, varscan2
- TFB1M | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 20/113 reads (18%) | catalogued as rs564006101, COSV51638041, COSV99265994; called by muse, mutect2, varscan2
- TMEM131L | c.3593T>G p.L1198R | Missense Mutation (SNP) | VAF 143/363 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.486); catalogued as COSV53641683; called by muse, mutect2, varscan2
- TNS1 | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs375150652; called by muse, mutect2, varscan2
- TPPP3 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs562124643, COSV52083510; called by muse, mutect2, varscan2
- TRIM51 | c.737A>T p.Q246L | Missense Mutation (SNP) | VAF 252/590 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV55264233; called by muse, mutect2, varscan2
- TRMT2A | c.1728G>C p.Q576H | Missense Mutation (SNP) | VAF 154/498 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs749424626, COSV99349933; called by muse, mutect2, varscan2
- TRPS1 | c.1045G>A p.E349K (on ENST00000220888 / NM_001330599.2; = p.E362K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); catalogued as rs757182048, COSV55226101; called by muse, mutect2, varscan2
- TTN | c.30909G>T p.Q10303H (on ENST00000591111; = p.Q9376H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 196/405 reads (48%) | PolyPhen benign (0); catalogued as COSV59910126; called by muse, mutect2, varscan2
- TXLNB | c.946C>A p.Q316K | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV62727145; called by muse, mutect2, varscan2
- UBE3B | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 116/290 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs766067011, COSV55091624; called by muse, mutect2, varscan2
- USP25 | c.1173C>A p.N391K | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.894); catalogued as COSV99583573; called by muse, mutect2, varscan2
- VPS37B | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs370211610, COSV99458231; called by muse, mutect2, varscan2
- VWC2L | c.436C>A p.H146N | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.61); catalogued as COSV100435566; called by muse, mutect2, varscan2
- WASHC5 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 97/181 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs376301577; called by muse, mutect2, varscan2
- WDR17 | c.3829C>T p.L1277F | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV54569223; called by muse, mutect2, varscan2
- XKR7 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 107/168 reads (64%) | SIFT tolerated (0.78); PolyPhen probably damaging (1); catalogued as rs749317124, COSV73813151; called by muse, mutect2, varscan2
- XRN2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426725850, COSV65868255; called by muse, mutect2, varscan2
- ZBTB49 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as rs750086879, COSV61924420, COSV61925194; called by muse, mutect2, varscan2
- ZBTB9 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201031785, COSV67702455, COSV99063429; called by muse, mutect2, varscan2
- ZC3H13 | c.1889A>T p.D630V | Missense Mutation (SNP) | VAF 101/457 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV54448422; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1765C>T p.L589F | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV99648447; called by muse, varscan2
- ZNF398 | c.1622G>A p.C541Y (on ENST00000475153 / NM_170686.3; = p.C370Y on NM_020781.4) | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60064648, COSV60066119; called by muse, mutect2
- ZNF439 | c.643A>T p.K215* | Nonsense Mutation (SNP) | VAF 52/282 reads (18%) | catalogued as COSV58308537; called by muse, mutect2, varscan2
- ZNF572 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 74/128 reads (58%) | catalogued as COSV60001298; called by muse, mutect2, varscan2
- ZNF574 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1189563727, COSV99725995; called by muse, mutect2, varscan2
- ZNF578 | c.1535A>C p.K512T | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV69736016; called by muse, mutect2, varscan2
- ZNF836 | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV59081333; called by muse, mutect2, varscan2
- ZSCAN1 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as COSV56602231; called by muse, mutect2, varscan2
- ADAM17 | c.1697_1700del p.V566Afs*58 | Frame Shift Del (DEL) | VAF 53/140 reads (38%) | called by mutect2, pindel, varscan2
- CFHR4 | c.186_188del p.S63del (on ENST00000367416 / NM_001201551.2; = p.S64del on NM_006684.5) | In Frame Del (DEL) | VAF 48/219 reads (22%) | called by mutect2, pindel, varscan2
- FBXW7 | c.1161dup p.Q388Tfs*5 (on ENST00000281708 / NM_001349798.2; = p.Q308Tfs*5 on NM_018315.5) | Frame Shift Ins (INS) | VAF 19/54 reads (35%) | called by mutect2, pindel, varscan2
- H4C11 | c.215_233del p.T72Sfs*? | Frame Shift Del (DEL) | VAF 114/276 reads (41%) | called by mutect2, varscan2
- MUC16 | c.43382C>T p.A14461V | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRAMEF7 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 92/1229 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2
- RPRD2 | c.2198_2199del p.P733Hfs*4 | Frame Shift Del (DEL) | VAF 39/107 reads (36%) | called by mutect2, pindel, varscan2
- WDR47 | c.1386_1388del p.E462del (on ENST00000369962 / NM_001142551.2; = p.E463del on NM_014969.5) | In Frame Del (DEL) | VAF 24/84 reads (29%) | called by pindel, varscan2
- ANKS1B | c.3246A>G p.Q1082= (on ENST00000547776 / NM_152788.4; = p.Q248= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/219 reads (11%) | catalogued as COSV59115636; called by muse, mutect2, varscan2
- ARHGEF17 | c.2220G>A p.Q740= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs1436754929, COSV55230023; called by mutect2, varscan2
- ATP13A1 | c.2685G>A p.R895= | Silent (SNP) | VAF 60/169 reads (36%) | catalogued as COSV52283059; called by muse, mutect2, varscan2
- CDH6 | c.2241G>A p.A747= | Silent (SNP) | VAF 91/197 reads (46%) | catalogued as rs868393947, COSV54064928; called by muse, mutect2, varscan2
- CIB2 | c.483C>T p.D161= | Silent (SNP) | VAF 20/214 reads (9%) | catalogued as rs199794998, COSV51947639; called by muse, mutect2
- CNBD1 | c.138C>T p.C46= | Silent (SNP) | VAF 88/244 reads (36%) | catalogued as COSV72916664; called by muse, mutect2, varscan2
- CNTNAP2 | c.1857C>T p.S619= | Silent (SNP) | VAF 187/350 reads (53%) | catalogued as rs753699122, COSV62149673; called by muse, mutect2, varscan2
- COL4A1 | c.4938G>A p.T1646= | Silent (SNP) | VAF 57/101 reads (56%) | catalogued as rs751179885, COSV65422116; called by muse, mutect2, varscan2
- CTDP1 | c.2694G>A p.T898= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs935450087, COSV99310400; called by muse, mutect2, varscan2
- ECHDC3 | c.798T>G p.A266= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV64867324; called by muse, mutect2, varscan2
- FADD | c.378C>T p.I126= | Silent (SNP) | VAF 105/237 reads (44%) | catalogued as rs61757382, COSV57228946; called by muse, mutect2, varscan2
- FBXO34 | c.1920G>A p.V640= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV58253510; called by muse, mutect2, varscan2
- GLI1 | c.3096G>A p.Q1032= | Silent (SNP) | VAF 63/245 reads (26%) | catalogued as COSV57358551; called by muse, mutect2, varscan2
- HIVEP3 | c.243C>A p.P81= | Silent (SNP) | VAF 136/521 reads (26%) | catalogued as rs371345318, COSV99912245; called by muse, mutect2, varscan2
- HNRNPLL | c.561T>A p.T187= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV55366881; called by muse, mutect2, varscan2
- ITGAV | c.2856G>A p.S952= | Silent (SNP) | VAF 30/204 reads (15%) | catalogued as rs769295279, COSV53709641; called by muse, mutect2, varscan2
- KCNH3 | c.1786C>T p.L596= | Silent (SNP) | VAF 39/135 reads (29%) | catalogued as COSV57789820; called by muse, mutect2, varscan2
- KIF26B | c.2817C>T p.S939= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as rs760386992, COSV63637541; called by muse, mutect2, varscan2
- METTL25 | c.204G>A p.E68= | Silent (SNP) | VAF 300/492 reads (61%) | catalogued as COSV50257738; called by muse, mutect2, varscan2
- MOAP1 | c.690C>T p.V230= | Silent (SNP) | VAF 33/158 reads (21%) | catalogued as COSV52092260; called by muse, mutect2, varscan2
- OR10H5 | c.402G>A p.V134= | Silent (SNP) | VAF 163/496 reads (33%) | catalogued as COSV58277521; called by muse, mutect2, varscan2
- OSBPL1A | c.1860G>A p.R620= (on ENST00000319481 / NM_080597.4; = p.R107= on NM_018030.4) | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as COSV60195720; called by muse, mutect2, varscan2
- PCARE | c.3600T>A p.G1200= | Silent (SNP) | VAF 100/208 reads (48%) | catalogued as COSV59053318; called by muse, mutect2, varscan2
- PCDHA8 | c.1824G>A p.S608= | Silent (SNP) | VAF 345/388 reads (89%) | catalogued as rs782207224, COSV65323792; called by muse, mutect2, varscan2
- PCDHAC2 | c.1761G>A p.S587= | Silent (SNP) | VAF 19/154 reads (12%) | catalogued as rs782634339, COSV53838691; called by muse, mutect2, varscan2
- PCDHB3 | c.708C>T p.N236= | Silent (SNP) | VAF 32/180 reads (18%) | catalogued as rs782533944, COSV50564702; called by muse, mutect2, varscan2
- PCNX1 | c.2427C>G p.L809= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV53090217; called by muse, mutect2, varscan2
- PRKCZ | c.1545C>T p.H515= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs371504744; called by muse, mutect2, varscan2
- PROK2 | c.219T>C p.R73= | Silent (SNP) | VAF 70/239 reads (29%) | catalogued as COSV55208373; called by muse, mutect2, varscan2
- PXDN | c.633G>A p.A211= | Silent (SNP) | VAF 78/232 reads (34%) | catalogued as rs754910107, COSV53241003, COSV99412510; called by muse, mutect2, varscan2
- PXDNL | c.2889G>A p.E963= | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as rs1023534889, COSV62479964; called by muse, mutect2, varscan2
- RAB12 | c.723C>T p.V241= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV61398106; called by muse, mutect2, varscan2
- RCOR2 | c.645A>C p.G215= | Silent (SNP) | VAF 47/161 reads (29%) | catalogued as COSV100036155, COSV56850066; called by muse, mutect2, varscan2
- RFX2 | c.1644C>T p.N548= | Silent (SNP) | VAF 83/199 reads (42%) | catalogued as rs35016808; called by muse, mutect2, varscan2
- SART1 | c.2352C>T p.I784= | Silent (SNP) | VAF 80/167 reads (48%) | catalogued as rs375131980; called by muse, mutect2, varscan2
- SEMA5B | c.2655C>A p.P885= | Silent (SNP) | VAF 76/154 reads (49%) | catalogued as COSV52091802; called by muse, mutect2, varscan2
- SHROOM3 | c.3648C>T p.A1216= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as rs778932431, COSV56024087; called by muse, mutect2, varscan2
- SLC26A8 | c.516G>A p.L172= | Silent (SNP) | VAF 74/139 reads (53%) | catalogued as COSV62884731; called by muse, mutect2, varscan2
- SLC6A17 | c.135C>A p.G45= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV58991515, COSV58991607; called by muse, mutect2
- SNTG2 | c.702C>T p.A234= | Silent (SNP) | VAF 47/89 reads (53%) | catalogued as rs776173570, COSV57970015; called by muse, mutect2, varscan2
- TCTE3 | c.312C>A p.V104= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as COSV64655549; called by muse, mutect2, varscan2
- TLX3 | c.171G>A p.P57= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV51539088; called by muse, mutect2, varscan2
- TTC25 | c.1692C>T p.S564= | Silent (SNP) | VAF 119/219 reads (54%) | catalogued as rs782082609, COSV66367592; called by muse, mutect2, varscan2
